FM case AD11 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/a2d1f9e8-1db5-4594-b5ac-05db7457b221

Female, 40.5 years: Clear cell carcinoma (ICD-O-3 8310/3) of the kidney; primary biopsied or resected from the kidney. Tumor nuclei on the sequenced sample's slide: 16% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
